Somatic mutation profile of tumor specimen PCProject_0653_T2_WES (aliquot PCProject_0653_T2_WES_1) from CMI case PCProject_0653, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.4 years (23,167 days).
Specimen PCProject_0653_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a99161b-6921-4027-9c4d-a0d534c41e64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0653_SALIVA (DNA), aliquot PCProject_0653_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb05e189-e378-4adb-ab63-f3e00fa9a97a

The open-access MAF lists 35 somatic variants for this specimen: 20 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 10, Intron 3, In Frame Del 2, Frame Shift Ins 2, RNA 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYSRT1 | c.325G>A p.A109T (on ENST00000409414; = p.A69T on NM_199001.5) | Missense Mutation (SNP) | VAF 67/459 reads (15%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs770200987, COSV100763121; called by muse, mutect2, varscan2
- DEPDC1 | c.1992_1994del p.D664del (on ENST00000456315 / NM_001114120.3; = p.D380del on NM_017779.6) | In Frame Del (DEL) | VAF 11/111 reads (10%) | catalogued as rs1301873090; called by pindel, varscan2
- EPX | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 32/838 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs1301424609; called by muse, mutect2
- MGAM2 | c.5492C>T p.P1831L | Missense Mutation (SNP) | VAF 12/251 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.998); catalogued as rs1265759874; called by muse, mutect2
- NRG1 | c.214G>A p.A72T (on ENST00000523534; = p.A219T on NM_013962.2) | Missense Mutation (SNP) | VAF 20/555 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1554493885; called by muse, mutect2
- PCDHA3 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 35/1101 reads (3%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.027); catalogued as rs782381789, COSV65366726; called by muse, mutect2
- PCDHB11 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 83/437 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1563963188, COSV53379942; called by muse, mutect2, varscan2
- PCDHB3 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 161/954 reads (17%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.026); catalogued as COSV50567547; called by muse, mutect2, varscan2
- RBBP8NL | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 81/593 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778678958; called by muse, mutect2, varscan2
- SPTB | c.5779G>A p.E1927K | Missense Mutation (SNP) | VAF 136/933 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.243); catalogued as rs1232851302, COSV67630720; called by muse, mutect2, varscan2
- SYNGAP1 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 28/812 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.369); catalogued as rs1212521412, COSV53381859; called by muse, mutect2
- ZFYVE26 | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 56/473 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1566894893, COSV61325896; called by muse, mutect2, varscan2
- CD58 | c.553dup p.I185Nfs*6 | Frame Shift Ins (INS) | VAF 12/135 reads (9%) | called by mutect2, pindel
- CLEC14A | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 48/318 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- KIF27 | c.3816A>C p.L1272F | Missense Mutation (SNP) | VAF 17/210 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- MGA | c.1468dup p.M490Nfs*9 | Frame Shift Ins (INS) | VAF 16/131 reads (12%) | called by mutect2, pindel, varscan2
- MGA | c.5174C>G p.S1725* | Nonsense Mutation (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2
- NT5E | c.1618C>G p.P540A | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SOX30 | c.235_237del p.L81del | In Frame Del (DEL) | VAF 65/404 reads (16%) | called by mutect2, pindel, varscan2
- TRIM64B | c.1026G>C p.W342C | Missense Mutation (SNP) | VAF 84/966 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANKFY1 | c.1599C>A p.S533= | Silent (SNP) | VAF 41/790 reads (5%) | catalogued as COSV58919200; called by muse, mutect2
- CD302 | c.18G>C p.L6= | Silent (SNP) | VAF 86/551 reads (16%) | called by muse, mutect2, varscan2
- CDH4 | c.1902G>A p.T634= | Silent (SNP) | VAF 156/1119 reads (14%) | catalogued as rs147023467; called by muse, mutect2, varscan2
- DSC3 | c.2364C>A p.T788= | Silent (SNP) | VAF 67/570 reads (12%) | catalogued as COSV64575492; called by muse, mutect2, varscan2
- KRT1 | c.1779C>T p.G593= | Silent (SNP) | VAF 147/907 reads (16%) | catalogued as rs745549570, COSV52865295; called by muse, mutect2, varscan2
- MBP | c.756C>T p.A252= (on ENST00000355994 / NM_001025101.2; = p.A134= on NM_002385.3) | Silent (SNP) | VAF 36/232 reads (16%) | catalogued as rs747179199; called by muse, mutect2
- POLL | c.1507C>T p.L503= | Silent (SNP) | VAF 30/676 reads (4%) | called by muse, mutect2
- RP1L1 | c.6645G>A p.P2215= | Silent (SNP) | VAF 170/1027 reads (17%) | catalogued as rs530023995, COSV66754304; called by muse, mutect2, varscan2
- UBAP2L | c.2760C>T p.L920= | Silent (SNP) | VAF 18/390 reads (5%) | called by muse, mutect2
- ZMYM1 | c.1842T>C p.S614= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as rs373033606; called by muse, mutect2, varscan2
- FMO9P | n.540G>A | RNA (SNP) | VAF 25/206 reads (12%) | catalogued as rs182628168; called by muse, mutect2, varscan2
- HMG20B | c.-18-37_-18-36insCGGGCCC | Intron (INS) | VAF 24/260 reads (9%) | called by mutect2, pindel
- LYRM4 | c.207+29741C>T | Intron (SNP) | VAF 4/31 reads (13%) | catalogued as rs1481687664; called by muse, mutect2
- RABEP1 | c.-76C>T | 5'UTR (SNP) | VAF 48/205 reads (23%) | called by muse, mutect2, varscan2
- TPP1 | c.886+45G>T | Intron (SNP) | VAF 57/430 reads (13%) | called by muse, mutect2, varscan2
